MMRF case MMRF_2506 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2faf3ba1-fd12-4cca-a362-5cb9d298e932

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.4 years (29,719 days); ISS stage: III; Days to last known disease status: 685 days (1.9 years); Days to last follow up: 685 days (1.9 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 370 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 369 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 0): M Protein 3.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.71 mg/dL; Immunoglobulin G 61.2 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 5.83 µg/mL; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 9.9 g/dL; Glucose 9.08 mmol/L.
- Day 92 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 7.94 g/L; Immunoglobulin A 1.4 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 8.14 mmol/L.
- Day 156 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.22 mg/dL; Immunoglobulin G 8.81 g/L; Immunoglobulin A 2.45 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 9.68 mmol/L.
- Day 243 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 9.11 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 2.02 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 6.99 mmol/L.
- Day 344 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.8 mg/dL; Immunoglobulin G 8.6 g/L; Immunoglobulin A 2.49 g/L; Immunoglobulin M 0.6 g/L; Beta 2 Microglobulin 2.67 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 8.8 mmol/L.
- Day 421 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 2.58 g/L; Immunoglobulin M 0.74 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 10.7 mmol/L.
- Day 509 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.86 g/L; Beta 2 Microglobulin 2.76 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 140 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.
- Day 593 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 2.62 g/L; Immunoglobulin M 1.06 g/L; Beta 2 Microglobulin 2.68 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 9.96 mmol/L.
- Day 685 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 2.57 g/L; Immunoglobulin M 1.04 g/L; Beta 2 Microglobulin 2.52 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 134 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 8.14 mmol/L.

Other clinical attributes
- Day -16: Weight: 87 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2506_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_2506_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
